MMRF case MMRF_2059 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/42004da4-4e43-4866-9739-dca2ddbbcf78

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.2 years (20,887 days); ISS stage: III; Days to last known disease status: 1,002 days (2.7 years); Days to last follow up: 1,002 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 43 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 46 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 74 days; Days to treatment end: 76 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 105 days; Days to treatment end: 105 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 839 days (2.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 2): M Protein 1.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 303 mg/dL; Immunoglobulin G 3.83 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 20 µg/mL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 1070 µmol/L; Blood Urea Nitrogen 22.1 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 6.49 mmol/L.
- Day 106 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12 mg/dL; Immunoglobulin G 4.93 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 8.82 µg/mL; Lactate Dehydrogenase 6.03 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.76 ×10⁹/L; Platelets 75 ×10⁹/L; Creatinine 460 µmol/L; Blood Urea Nitrogen 17.1 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 5.4 g/dL; Glucose 4.29 mmol/L.
- Day 187 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 6.56 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 292 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.13 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL; Glucose 6.22 mmol/L.
- Day 257 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 5.84 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 382 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.1 g/dL; Glucose 5.61 mmol/L.
- Day 348 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.19 mg/dL; Immunoglobulin G 7.57 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 190 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.25 mmol/L; Albumin 45 g/L; Total Protein 6.4 g/dL; Glucose 6 mmol/L.
- Day 446 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 6.69 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 9.6 µg/mL; Hemoglobin 7.07 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 472 µmol/L; Blood Urea Nitrogen 28.2 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 3.41 mmol/L.
- Day 537 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 5.95 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 6.45 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 329 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 5.12 mmol/L.
- Day 628 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.8 mg/dL; Immunoglobulin G 0.73 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 383 µmol/L; Blood Urea Nitrogen 26.4 mmol/L; Calcium 2.13 mmol/L; Albumin 45 g/L; Total Protein 6.3 g/dL; Glucose 4.95 mmol/L.
- Day 718 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.45 mg/dL; Immunoglobulin G 6.73 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.53 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 349 µmol/L; Blood Urea Nitrogen 29.3 mmol/L; Calcium 2.25 mmol/L; Albumin 48 g/L; Total Protein 6.8 g/dL; Glucose 4.95 mmol/L.
- Day 810 (ECOG 2): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.4 mg/dL; Immunoglobulin G 5.07 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 388 µmol/L; Blood Urea Nitrogen 27.1 mmol/L; Calcium 2.35 mmol/L; Albumin 48 g/L; Total Protein 6.8 g/dL; Glucose 4.79 mmol/L.
- Day 894 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.93 mg/dL; Immunoglobulin G 4.34 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 4.43 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 392 µmol/L; Blood Urea Nitrogen 27.1 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 4.73 mmol/L.
- Day 1,002 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.26 mg/dL; Immunoglobulin G 4.49 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 370 µmol/L; Blood Urea Nitrogen 26.1 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 3.52 mmol/L.

Other clinical attributes
- Day 1: Weight: 92 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2059_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2059_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
